Somatic mutation profile of tumor specimen TCGA-M8-A5N4-01A (aliquot TCGA-M8-A5N4-01A-11D-A26I-08) from TCGA case TCGA-M8-A5N4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen TCGA-M8-A5N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1590a72b-5e32-4a2a-9351-25cbaa3f430f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M8-A5N4-10A (Blood Derived Normal), aliquot TCGA-M8-A5N4-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/906ce5a4-e3f6-408a-a940-48b94c7cde50

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 19, Silent 13, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4316G>C p.C1439S | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100710464; called by muse, mutect2, varscan2
- ATAD2B | c.4193G>A p.R1398H | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53199395; called by muse, mutect2
- ATF6B | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 38/490 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV100913542; called by muse, mutect2
- CCDC85A | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756124844, COSV101339411; called by muse, mutect2, varscan2
- CDKN2A | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100445873; called by muse, varscan2
- CEP112 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 21/295 reads (7%) | catalogued as rs747219039, COSV101210611; called by muse, mutect2
- FERMT1 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 97/566 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99451280; called by muse, mutect2, varscan2
- FRMPD1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 77/415 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs772039667, COSV63383427; called by muse, mutect2, varscan2
- HPR | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 101/650 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99930831; called by muse, mutect2, varscan2
- ICA1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755663034, COSV55576081; called by muse, mutect2, varscan2
- LRP10 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.248); catalogued as rs1440462319, COSV100612322; called by muse, mutect2, varscan2
- RIMS1 | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99325068; called by muse, mutect2, varscan2
- RIMS4 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV65720998; called by muse, mutect2
- SIPA1L3 | c.3313G>A p.G1105S | Missense Mutation (SNP) | VAF 60/820 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs373059257, COSV55920093; called by muse, mutect2
- SLC13A4 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 182/955 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1306234161, COSV62460030; called by muse, mutect2, varscan2
- SPEN | c.10522G>A p.V3508M | Missense Mutation (SNP) | VAF 137/755 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs1405875555, COSV100998985; called by muse, mutect2, varscan2
- TAOK2 | c.449G>C p.R150T | Missense Mutation (SNP) | VAF 124/601 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664135; called by muse, mutect2, varscan2
- TBCK | c.844C>T p.P282S (on ENST00000273980 / NM_001163436.4; = p.P219S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/345 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs538717258, COSV99912242; called by muse, varscan2
- WDR17 | c.3955C>T p.L1319F | Missense Mutation (SNP) | VAF 79/535 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99707100; called by muse, mutect2, varscan2
- ZSWIM2 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200253183; called by muse, mutect2
- ABCC9 | c.3993C>T p.H1331= | Silent (SNP) | VAF 46/532 reads (9%) | catalogued as rs377704379; ClinVar: likely benign; called by muse, mutect2
- C7orf33 | c.159C>T p.G53= | Silent (SNP) | VAF 92/647 reads (14%) | catalogued as rs549712040, COSV61023355; called by muse, mutect2, varscan2
- CORIN | c.1056C>T p.D352= | Silent (SNP) | VAF 37/221 reads (17%) | catalogued as rs574925971, COSV99903192; called by muse, mutect2, varscan2
- OR5D14 | c.750C>T p.I250= | Silent (SNP) | VAF 33/570 reads (6%) | catalogued as COSV100162244; called by muse, mutect2
- OR6Y1 | c.669C>T p.Y223= | Silent (SNP) | VAF 57/408 reads (14%) | catalogued as rs537972026, COSV56928838; called by muse, mutect2, varscan2
- P2RY4 | c.750G>T p.V250= | Silent (SNP) | VAF 40/274 reads (15%) | catalogued as COSV100996994; called by muse, mutect2, varscan2
- RASL10B | c.36G>A p.A12= | Silent (SNP) | VAF 60/339 reads (18%) | catalogued as rs781956889; called by muse, mutect2, varscan2
- RFPL3 | c.816C>T p.S272= (on ENST00000249007 / NM_001098535.1; = p.S243= on NM_006604.2) | Silent (SNP) | VAF 98/558 reads (18%) | catalogued as rs759102145, COSV99966973, COSV99967279; called by muse, varscan2
- SLC29A4 | c.327C>T p.S109= | Silent (SNP) | VAF 42/366 reads (11%) | catalogued as COSV99786692; called by muse, mutect2, varscan2
- SPAM1 | c.99C>T p.C33= | Silent (SNP) | VAF 55/306 reads (18%) | catalogued as COSV99772824; called by muse, mutect2, varscan2
- SPATA31D1 | c.486G>A p.S162= | Silent (SNP) | VAF 87/508 reads (17%) | catalogued as rs575416308, COSV61194177; called by muse, mutect2, varscan2
- TRPC7 | c.264C>T p.N88= | Silent (SNP) | VAF 104/683 reads (15%) | catalogued as rs373243219; called by muse, mutect2, varscan2
- TTBK2 | c.3210G>A p.S1070= | Silent (SNP) | VAF 127/646 reads (20%) | catalogued as rs750352266, COSV99141196; called by muse, mutect2, varscan2
